Gene-level copy-number profile of tumor specimen TCGA-T9-A92H-01A from TCGA case TCGA-T9-A92H, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 82.3 years (30,058 days).
Specimen TCGA-T9-A92H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.54d94801-de1e-4c0e-8640-87299b0ce19d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-T9-A92H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/35dc84fd-26e4-4636-bf9e-66bbc3b8b380

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 39; copy number 2: 6,540; copy number 3: 16,970; copy number 4: 31,653; copy number 5: 979; copy number 6: 1,496; copy number 7: 1,158; copy number 8: 500; copy number 10: 355; copy number 11: 25; copy number 12: 87.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-T9-A92H-01A-11D-A36W-01): tumor purity 0.68, ploidy 3.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,380,476–7,004,112, 7 genes: AC006112.1, AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P, RNU6-328P.
- chr20:14,933,843–15,022,958, 3 genes: AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 467 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:10,326,434–12,803,887, 82 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr16:15,395,754–16,223,522, 20 genes, copy number 10 (within-gene range 5–10): AC140504.1, BMERB1, MARF1, AC026401.1, MIR6506, NDE1, MIR484, AC026401.2, AC026401.3, MYH11, AF001548.2, AF001548.1, AF001548.3, CEP20, RNU6-213P, AC130651.1, RPL15P20, ABCC1, RPL17P40, ABCC6.
- chr16:20,155,648–23,026,285, 89 genes, copy number 10 (broad region; genes not listed).
- chr16:26,721,874–29,370,272, 89 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr16:52,436,417–53,392,473, 25 genes, copy number 11: TOX3, AC007490.1, CASC16, AC026462.5, AC026462.3, AC026462.2, AC026462.4, AC026462.1, PHBP21, AC007346.1, AC007346.2, AC007906.2, CHD9, AC007906.1, AC079416.4, AC079416.2, AC079416.3, AC079416.1, RNA5SP427, AC007342.2, AC007342.3, AC007342.4, AC007342.5, AC007342.8, AC007342.9.
- chr16:57,140,896–59,199,395, 75 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr20:31,257,664–33,329,969, 87 genes, copy number 12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 39. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
